Gene-level copy-number profile of tumor specimen TCGA-EO-A2CG-01A from TCGA case TCGA-EO-A2CG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 69.2 years (25,279 days).
Specimen TCGA-EO-A2CG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.06834dfb-7b97-4e1e-9716-cfaf47d15141.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A2CG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f304895-b8c7-43be-82e1-f6916cf0c601

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 909; copy number 2: 15,433; copy number 3: 18,831; copy number 4: 15,191; copy number 5: 6,011; copy number 6: 502; copy number 7: 1,949; copy number 8: 220; copy number 9: 270; copy number 10: 59; copy number 11: 9; copy number 12: 36; copy number 13: 98; copy number 14: 43; copy number 15: 4; copy number 16: 69; copy number 17: 1; copy number 18: 101; copy number 19: 1; copy number 20: 5; copy number 24: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A2CG-01A-12D-A17U-01): tumor purity 0.46, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,934 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–1,744,852, 37 genes, copy number 8: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN.
- chr2:1,795,525–1,828,667, 2 genes, copy number 8: AC093390.2, AC093390.1.
- chr2:28,683,976–30,644,225, 32 genes, copy number 9 (within-gene range 5–9): RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4, ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1, AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5, LBH, AC109642.1, LINC01936, AC073255.1, LCLAT1.
- chr2:77,652,025–79,185,523, 17 genes, copy number 12–18: AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1.
- chr2:81,967,079–82,866,508, 13 genes, copy number 7 (within-gene range 4–7): RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3.
- chr4:49,096–4,542,346, 147 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr4:48,497,357–58,565,212, 157 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr5:58,198–2,262,023, 79 genes, copy number 7–18 (broad region; genes not listed).
- chr5:8,572,047–12,804,363, 73 genes, copy number 13–24 (within-gene range 5–24) (broad region; genes not listed).
- chr5:41,585,882–43,348,716, 42 genes, copy number 9: AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1.
- chr5:102,131,007–102,146,874, 2 genes, copy number 8: RNA5SP188, AC008948.1.
- chr7:94,907,202–97,998,622, 57 genes, copy number 14–18: PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1, AP1S2P1, RN7SKP104, TAC1, ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.4, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P.
- chr7:107,743,949–111,562,517, 33 genes, copy number 10–12 (within-gene range 3–12): CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, AC073326.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1.
- chr7:112,206,695–113,146,330, 21 genes, copy number 12 (within-gene range 7–12): ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30.
- chr8:70,051,651–73,295,789, 50 genes, copy number 8–11: PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7.
- chr8:92,351,912–92,965,645, 10 genes, copy number 7 (within-gene range 4–7): AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1.
- chr8:115,950,511–116,325,062, 1 gene, copy number 8 (within-gene range 6–8): LINC00536.
- chr8:116,289,622–128,564,679, 187 genes, copy number 7–8 (broad region; genes not listed).
- chr9:28,539,735–31,381,490, 21 genes, copy number 7–15: AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243.
- chr10:74,151,202–78,697,022, 76 genes, copy number 10–20 (within-gene range 2–20) (broad region; genes not listed).
- chr10:81,136,540–81,137,335, 1 gene, copy number 7: RPA2P2.
- chr15:98,437,162–100,437,914, 41 genes, copy number 7 (within-gene range 5–7): FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4, DNM1P46, AC090825.2, RN7SL484P, AC090825.1, AC084855.1, ADAMTS17, AC084855.2, RNA5SP402, AC022710.1, SPATA41, CERS3-AS1.
- chr17:8,356,902–9,576,591, 24 genes, copy number 7 (within-gene range 4–7): KRBA2, AC135178.4, AC135178.3, RPL26, RNF222, NDEL1, MYH10, RNU7-43P, PPIAP52, AC025518.1, CCDC42, SPDYE4, MFSD6L, PIK3R6, PIK3R5, AC002091.2, AC002091.1, NTN1, AC005695.1, AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2.
- chr19:8,173,272–12,237,767, 226 genes, copy number 9–17 (within-gene range 2–17) (broad region; genes not listed).
- chr19:27,638,483–33,067,433, 111 genes, copy number 7–9 (broad region; genes not listed).
- chr19:35,487,324–58,605,223, 1,472 genes, copy number 7 (broad region; genes not listed).
- chr22:28,992,721–29,031,476, 2 genes, copy number 7: ZNRF3-IT1, ZNRF3-AS1.

Autosomal genes at a single copy (total copy number 1): 909. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
